Somatic mutation profile of tumor specimen C3N-02237-03 (aliquot CPT0214850009) from CPTAC case C3N-02237, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.7 years (25,474 days).
Specimen C3N-02237-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61338485-f901-4197-8ded-ef61bf6ec4f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02237-71 (Blood Derived Normal), aliquot CPT0214950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18dfbca3-bbea-4684-b4fb-9ad46207fdbb

The open-access MAF lists 271 somatic variants for this specimen: 179 protein-altering or splice-affecting, 53 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 53, Intron 21, Nonsense Mutation 15, 3'UTR 8, Splice Site 6, RNA 4, 5'Flank 4, Splice Region 2, 5'UTR 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 66/258 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 31/323 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV52468782; called by muse, mutect2
- AFF2 | c.2691-1G>T p.X897_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99661330; called by muse, varscan2
- AMBN | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.697); catalogued as COSV100534544; called by muse, mutect2, varscan2
- APOC2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs148445956; called by muse, mutect2
- ASCC3 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 8/174 reads (5%) | catalogued as COSV61230679; called by muse, mutect2
- ASMTL | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV101187626; called by muse, mutect2
- ASZ1 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.998); catalogued as rs767070581; called by muse, mutect2
- C1orf158 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 52/535 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs757604143, COSV55346313, COSV55347418; called by muse, mutect2
- C8A | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV100776478, COSV63486563; called by muse, mutect2
- CASR | c.2887C>A p.Q963K (on ENST00000490131; = p.Q1040K on NM_000388.4) | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV56141063; called by muse, mutect2, varscan2
- CDH10 | c.2099G>T p.R700M | Missense Mutation (SNP) | VAF 28/433 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as COSV100053425; called by muse, mutect2
- COL1A2 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 35/558 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM930151; called by muse, mutect2
- EFL1 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs1264595307; called by muse, mutect2
- ELFN2 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.513); catalogued as COSV68744370; called by muse, mutect2
- FIBIN | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV59412390; called by muse, mutect2
- FOXI3 | c.516C>A p.Y172* | Nonsense Mutation (SNP) | VAF 56/560 reads (10%) | catalogued as COSV67916997; called by muse, mutect2
- FRMD7 | c.1998T>A p.Y666* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV53747069; called by muse, mutect2, varscan2
- GPATCH2 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255013419; called by muse, mutect2
- GPIHBP1 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 38/564 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV58209660; called by muse, mutect2
- HK3 | c.1931G>C p.R644P | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52837709; called by muse, mutect2
- IQSEC2 | c.2825G>A p.R942Q (on ENST00000642864 / NM_001111125.3; = p.R737Q on NM_015075.2) | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs782651121, COSV100944910; called by muse, mutect2
- KIF16B | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 17/208 reads (8%) | catalogued as COSV61710244; called by muse, mutect2
- LIPC | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 44/513 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760729045, COSV54421077, COSV54426754; called by muse, mutect2
- MIF4GD | c.243C>A p.N81K (on ENST00000325102 / NM_001370592.1; = p.N115K on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.455); catalogued as COSV55454454; called by muse, mutect2
- MYH2 | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV55432112; called by muse, mutect2
- NAA38 | c.307A>G p.M103V (on ENST00000575771 / NM_001320925.2; = p.M151V on NM_032356.5) | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); catalogued as COSV54681277; called by muse, mutect2
- NCAM2 | c.2334A>T p.R778S | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53064973; called by muse, mutect2
- NEU1 | c.727G>T p.G243* | Nonsense Mutation (SNP) | VAF 30/593 reads (5%) | catalogued as CM003464; called by muse, mutect2
- ONECUT3 | c.1299C>A p.F433L | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66639376; called by muse, mutect2
- OR4A15 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.941); catalogued as COSV59033863; called by muse, mutect2
- PDGFB | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs776409973, COSV58648065; called by muse, mutect2
- PGK2 | c.614T>A p.V205E | Missense Mutation (SNP) | VAF 22/353 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59162695; called by muse, mutect2
- PLXNB2 | c.4174A>T p.R1392W | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63780000; called by muse, mutect2
- RBM10 | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 20/139 reads (14%) | catalogued as COSV61312393; called by muse, mutect2, varscan2
- RXFP2 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53635977; called by muse, mutect2
- SARM1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 21/250 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1490277771; called by muse, mutect2
- SCN3A | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99328442; called by muse, mutect2
- SEC14L4 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs768321574; called by muse, mutect2
- SIGLEC1 | c.4291C>A p.L1431M | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV52468152; called by muse, mutect2, varscan2
- SLITRK2 | c.1537G>C p.G513R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100158071; called by muse, mutect2, varscan2
- SPATA31D1 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV61195007; called by muse, mutect2
- SPON1 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868971848, COSV59959401; called by muse, mutect2, varscan2
- TMPRSS13 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 98/702 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs200462399; called by muse, varscan2
- TTC30B | c.1423T>C p.Y475H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1332800559, COSV68809220; called by muse, mutect2
- VWA5B2 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 23/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56611964; called by muse, mutect2
- ZFPM1 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs990429969, COSV100128760; called by muse, mutect2
- ZNF208 | c.2615G>A p.W872* | Nonsense Mutation (SNP) | VAF 28/340 reads (8%) | catalogued as rs766715279; called by muse, mutect2
- ZNF318 | c.6346G>T p.G2116C | Missense Mutation (SNP) | VAF 18/309 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV100545941; called by muse, mutect2
- ZNF358 | c.962G>T p.C321F | Missense Mutation (SNP) | VAF 45/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51176458; called by muse, mutect2
- ZNF521 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64125812, COSV64129437; called by muse, mutect2
- ZNF837 | c.872G>C p.R291P | Missense Mutation (SNP) | VAF 51/481 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101436179; called by muse, mutect2, varscan2
- ZNF865 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.02); catalogued as rs747896433; called by muse, mutect2, varscan2
- ABCD2 | c.1318A>G p.R440G | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AGBL4 | c.97A>T p.T33S | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.5255C>A p.P1752H | Missense Mutation (SNP) | VAF 59/599 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALKBH8 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- ANAPC2 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- ANKAR | c.415T>G p.Y139D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2
- ARL14EPL | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.062); called by muse, mutect2
- ATP12A | c.2650T>C p.Y884H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); called by muse, mutect2
- BEND5 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2
- BHLHE22 | c.70A>T p.S24C | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- BICRA | c.1242C>A p.F414L | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- BNC1 | c.1086T>A p.C362* | Nonsense Mutation (SNP) | VAF 28/211 reads (13%) | called by muse, mutect2, varscan2
- C1orf167 | c.1706T>A p.L569Q | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); called by muse, mutect2
- C4orf54 | c.4262C>A p.P1421Q | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CABS1 | c.977C>G p.P326R | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH26 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CES1 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2
- CHSY3 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- CHUK | c.798-1G>C p.X266_splice | Splice Site (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- CMYA5 | c.10153G>T p.A3385S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, mutect2
- COL13A1 | c.1279G>A p.G427R (on ENST00000398978 / NM_001130103.2; = p.G370R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- COL16A1 | c.2068C>A p.P690T | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); called by muse, mutect2
- COL18A1 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- COL26A1 | c.941-2A>T p.X314_splice (on ENST00000313669 / NM_001278563.3; = p.X312_splice on NM_133457.4) | Splice Site (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- CSMD1 | c.1376A>G p.E459G (on ENST00000520002; = p.E458G on NM_033225.6) | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- DCHS2 | c.1217T>G p.V406G | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDB1 | c.2287A>T p.S763C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX29 | c.3483C>G p.C1161W | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DHX58 | c.1041G>C p.E347D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- DHX9 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); called by muse, mutect2
- DNAJC6 | c.1999C>G p.P667A | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.358); called by muse, mutect2
- EBF1 | c.292-2A>T p.X98_splice | Splice Site (SNP) | VAF 17/305 reads (6%) | called by muse, mutect2
- EFR3A | c.1869G>T p.K623N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by mutect2, varscan2
- ELOVL7 | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ERCC6 | c.2429A>T p.D810V | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EYA4 | c.1149T>A p.D383E (on ENST00000531901 / NM_001301013.1; = p.D377E on NM_004100.5) | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- FAM177B | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2
- FBXO43 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.581); called by muse, mutect2
- FHAD1 | c.836A>T p.K279M | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- FRAS1 | c.2053C>A p.L685M | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.653); called by muse, mutect2
- FRZB | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- FUT9 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- GABRB3 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 32/518 reads (6%) | PolyPhen benign (0.176); called by muse, mutect2
- GARNL3 | c.904A>T p.I302F | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GLI3 | c.2815G>T p.G939W | Missense Mutation (SNP) | VAF 117/873 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIPAP1 | c.1613A>C p.Q538P | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- GRM8 | c.1582A>T p.T528S | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HSD3B1 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 17/385 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); called by muse, mutect2
- IGHA1 | c.574T>A p.C192S | Missense Mutation (SNP) | VAF 44/558 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); called by muse, mutect2
- IGSF11 | c.355C>T p.Q119* (on ENST00000393775 / NM_001015887.3; = p.Q118* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/369 reads (4%) | called by muse, mutect2
- IGSF21 | c.306-2A>T p.X102_splice | Splice Site (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- IL9R | c.603T>G p.I201M | Missense Mutation (SNP) | VAF 31/395 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- IPO5 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.317); called by muse, mutect2
- ISM2 | c.228C>A p.H76Q | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); called by muse, mutect2
- ITPR1 | c.2816G>T p.G939V (on ENST00000354582; = p.G924V on NM_002222.7) | Missense Mutation (SNP) | VAF 56/321 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNB2 | c.1482G>T p.W494C | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNQ2 | c.2596G>T p.G866C (on ENST00000359125 / NM_172107.4; = p.G838C on NM_004518.6) | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- KERA | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF13B | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 36/471 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.113); called by muse, mutect2
- LAMA4 | c.911G>T p.G304V (on ENST00000230538 / NM_001105206.3; = p.G297V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/674 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LSM14A | c.714A>T p.R238= | Splice Region (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- LYSMD2 | c.530G>T p.R177I | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2
- MCTP2 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC12 | c.13555G>T p.G4519C (on ENST00000379442; = p.G4376C on NM_001164462.1) | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC12 | c.13556G>T p.G4519V (on ENST00000379442; = p.G4376V on NM_001164462.1) | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC17 | c.4378A>G p.I1460V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH8 | c.5368G>T p.E1790* | Nonsense Mutation (SNP) | VAF 52/511 reads (10%) | called by muse, mutect2
- NAV3 | c.6291+2T>A p.X2097_splice (on ENST00000397909 / NM_001024383.2; = p.X2075_splice on NM_014903.6) | Splice Site (SNP) | VAF 7/55 reads (13%) | called by muse, varscan2
- NEB | c.17104T>A p.Y5702N | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFKBIZ | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NINL | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- NPHS1 | c.3560G>T p.G1187V | Missense Mutation (SNP) | VAF 45/431 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- OR2M3 | c.790T>A p.S264T | Missense Mutation (SNP) | VAF 23/513 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2
- OR5T1 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- OR9Q2 | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- OTP | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.365); called by muse, mutect2
- PCDH15 | c.3265A>T p.I1089F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCDHA7 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.154); called by muse, mutect2
- PCF11 | c.4478C>T p.S1493F | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PIF1 | c.1526G>T p.R509I | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2
- PILRA | c.454+4A>T | Splice Region (SNP) | VAF 26/429 reads (6%) | called by muse, mutect2
- PKHD1 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, mutect2
- PPA2 | c.217A>G p.K73E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R37 | c.658A>T p.S220C | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRDM13 | c.2007G>T p.E669D | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- PRPS1L1 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 60/623 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2
- PSIP1 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- PTPRQ | c.4750C>G p.P1584A (on ENST00000616559; = p.P1542A on NM_001145026.2) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- PTRH2 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 34/159 reads (21%) | called by muse, mutect2, varscan2
- RAET1G | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 48/839 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); called by muse, mutect2
- RET | c.1244G>C p.R415T | Missense Mutation (SNP) | VAF 46/457 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.159); called by muse, mutect2
- RPTN | c.1242C>A p.H414Q | Missense Mutation (SNP) | VAF 46/464 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2
- SAMD15 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SCN9A | c.2032G>C p.D678H (on ENST00000303354; = p.D667H on NM_002977.3) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- SLC41A2 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); called by muse, mutect2
- SLC44A1 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- SLC7A13 | c.241T>G p.Y81D | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC9A7 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SNAPC4 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.313); called by muse, mutect2
- SNTG1 | c.1342A>C p.S448R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- SOX30 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- SPAG7 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2
- SPATA31A1 | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 32/623 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SSC5D | c.1213G>C p.G405R | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 64/448 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- SYDE1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF5L | c.1610G>T p.W537L | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBX5 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TET1 | c.5219G>T p.R1740L | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.115); called by muse, mutect2
- TGM7 | c.839G>T p.W280L | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMC3 | c.283A>T p.T95S | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.093); called by muse, mutect2
- TMEM131 | c.3627dup p.S1210Efs*3 | Frame Shift Ins (INS) | VAF 21/229 reads (9%) | called by mutect2, pindel
- TRAPPC4 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2
- TRH | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 45/399 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TTC17 | c.2101G>T p.A701S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- VN1R4 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.426); called by muse, mutect2
- WAPL | c.2935G>T p.D979Y | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNK2 | c.6557T>A p.L2186Q (on ENST00000297954 / NM_001282394.1; = p.L2149Q on NM_006648.3) | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WTAP | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2
- ZEB1 | c.1094A>T p.N365I | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ZFHX4 | c.10088C>A p.A3363D | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- ZNF585B | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ZNF737 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ZSCAN18 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- ADAM33 | c.2316A>G p.G772= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- ADGRF4 | c.1536C>T p.S512= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs372352781; called by muse, mutect2, varscan2
- ADH4 | c.732T>G p.T244= | Silent (SNP) | VAF 45/374 reads (12%) | called by muse, mutect2, varscan2
- AHRR | c.900G>A p.A300= | Silent (SNP) | VAF 41/321 reads (13%) | catalogued as rs542713317, COSV57082928; called by muse, mutect2, varscan2
- ARHGEF2 | c.2388C>T p.A796= (on ENST00000361247 / NM_001162383.2; = p.A768= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 48/455 reads (11%) | called by muse, mutect2
- ARMH1 | c.1227C>T p.G409= | Silent (SNP) | VAF 17/388 reads (4%) | called by muse, mutect2
- ATP6V0D2 | c.1011G>A p.Q337= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- CHRNA9 | c.990C>A p.A330= | Silent (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- CLIP2 | c.2184C>T p.A728= | Silent (SNP) | VAF 28/478 reads (6%) | catalogued as rs540082073; called by muse, mutect2
- CPEB1 | c.1563G>A p.G521= (on ENST00000617958; = p.G456= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- DIPK2B | c.1209C>A p.A403= | Silent (SNP) | VAF 34/174 reads (20%) | called by muse, mutect2, varscan2
- DNAH5 | c.7221T>G p.P2407= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- E2F1 | c.1179C>T p.G393= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs1388938377; called by muse, mutect2, varscan2
- ENOX2 | c.369A>G p.R123= (on ENST00000338144 / NM_001382520.1; = p.R94= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- F8 | c.6303C>T p.H2101= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as rs375301013; called by muse, mutect2
- FA2H | c.669A>G p.T223= | Silent (SNP) | VAF 27/266 reads (10%) | called by muse, mutect2, varscan2
- FKRP | c.1365C>T p.A455= | Silent (SNP) | VAF 34/370 reads (9%) | called by muse, mutect2
- FRMD1 | c.75G>T p.A25= | Silent (SNP) | VAF 11/166 reads (7%) | called by muse, mutect2
- GOLGA8S | c.1368G>A p.L456= | Silent (SNP) | VAF 74/1029 reads (7%) | catalogued as rs775270833; called by muse, mutect2
- H2BC7 | c.171C>G p.S57= | Silent (SNP) | VAF 32/536 reads (6%) | called by muse, mutect2
- KCNRG | c.276T>C p.R92= | Silent (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2, varscan2
- LCE2B | c.276T>C p.C92= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs1193853523; called by muse, mutect2
- MALRD1 | c.2175C>T p.F725= | Silent (SNP) | VAF 13/173 reads (8%) | called by muse, mutect2
- MGMT | c.474G>T p.A158= (on ENST00000306010; = p.A127= on NM_002412.5) | Silent (SNP) | VAF 15/193 reads (8%) | catalogued as COSV60022206; called by muse, mutect2
- MYH11 | c.954A>T p.P318= | Silent (SNP) | VAF 43/341 reads (13%) | called by muse, mutect2, varscan2
- NLRP1 | c.4182A>G p.T1394= (on ENST00000572272 / NM_033004.4; = p.T1350= on NM_014922.5) | Silent (SNP) | VAF 41/379 reads (11%) | called by muse, mutect2, varscan2
- NWD1 | c.897C>T p.R299= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- OR2L2 | c.342G>T p.L114= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- OR4C13 | c.735C>A p.V245= | Silent (SNP) | VAF 26/159 reads (16%) | called by muse, mutect2, varscan2
- OR5I1 | c.204A>G p.L68= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- PABPC5 | c.1125G>C p.L375= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- PCDHA4 | c.2280T>G p.S760= | Silent (SNP) | VAF 32/395 reads (8%) | catalogued as COSV63539604; called by muse, mutect2
- PDS5B | c.2184T>C p.Y728= | Silent (SNP) | VAF 23/324 reads (7%) | called by muse, mutect2
- PKHD1 | c.7173G>C p.L2391= | Silent (SNP) | VAF 38/424 reads (9%) | catalogued as rs765985090; called by muse, mutect2
- PLPPR4 | c.1815C>T p.G605= | Silent (SNP) | VAF 23/202 reads (11%) | called by muse, mutect2, varscan2
- PLXNA4 | c.2499C>A p.T833= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as COSV100325859; called by muse, mutect2, varscan2
- PPFIA1 | c.474G>A p.V158= | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as COSV54131244; called by muse, mutect2
- RPP30 | c.54G>T p.L18= | Silent (SNP) | VAF 30/389 reads (8%) | called by muse, mutect2
- RXFP3 | c.975C>A p.T325= | Silent (SNP) | VAF 30/343 reads (9%) | called by muse, mutect2
- SHOX2 | c.804G>T p.L268= (on ENST00000441443 / NM_006884.3; = p.L292= on NM_003030.4) | Silent (SNP) | VAF 18/336 reads (5%) | called by muse, mutect2
- SLC25A33 | c.840G>T p.R280= | Silent (SNP) | VAF 34/411 reads (8%) | called by muse, mutect2
- SLC5A1 | c.1761C>T p.T587= | Silent (SNP) | VAF 44/376 reads (12%) | called by muse, mutect2, varscan2
- SLC6A19 | c.381G>C p.L127= | Silent (SNP) | VAF 84/719 reads (12%) | called by muse, mutect2, varscan2
- SORCS3 | c.2466G>T p.R822= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV63794728; called by muse, mutect2
- SPART | c.1083A>G p.L361= | Silent (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- SZT2 | c.3339T>G p.P1113= (on ENST00000634258 / NM_001365999.1; = p.P1056= on NM_015284.4) | Silent (SNP) | VAF 52/249 reads (21%) | called by muse, mutect2, varscan2
- TRPM2 | c.4485A>T p.A1495= | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- TRPM4 | c.1191G>T p.L397= | Silent (SNP) | VAF 34/343 reads (10%) | called by muse, mutect2, varscan2
- TTBK1 | c.3708C>T p.P1236= | Silent (SNP) | VAF 34/315 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.19434C>T p.Y6478= (on ENST00000591111; = p.Y5551= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- TTN | c.11356T>C p.L3786= (on ENST00000591111; = p.L3740= on NM_003319.4) | Silent (SNP) | VAF 18/235 reads (8%) | catalogued as rs587780988; ClinVar: uncertain significance / benign; called by muse, mutect2
- ZNF143 | c.1329T>A p.T443= | Silent (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2, varscan2
- ZNF558 | c.864G>T p.G288= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- AC116366.2 | c.-637-16137T>G | Intron (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- ACADS | chr12:120725824 G>T | 5'Flank (SNP) | VAF 44/423 reads (10%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3270+24G>T | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- C1QTNF6 | c.289+796G>A | Intron (SNP) | VAF 34/316 reads (11%) | catalogued as rs542188315; called by muse, mutect2
- CDKN2B | c.-2G>A | 5'UTR (SNP) | VAF 42/456 reads (9%) | called by muse, mutect2
- CPLX2 | c.208-105G>C | Intron (SNP) | VAF 24/305 reads (8%) | called by muse, mutect2
- DCTN3 | c.268+100A>C | Intron (SNP) | VAF 42/337 reads (12%) | called by muse, mutect2, varscan2
- DIS3L2 | c.2497-249C>T | Intron (SNP) | VAF 18/281 reads (6%) | catalogued as rs1437574696; called by muse, mutect2
- DUSP15 | c.426+987G>T | Intron (SNP) | VAF 50/612 reads (8%) | called by muse, mutect2
- DYRK4 | chr12:4588943 A>G | 5'Flank (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- DYSF | c.458-456G>T | Intron (SNP) | VAF 23/243 reads (9%) | catalogued as COSV50510758; called by muse, mutect2
- FKBP10 | chr17:41812996 C>A | 5'Flank (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- GCNT2P1 | n.817G>A | RNA (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- GRAMD1B | c.234+837A>T | Intron (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- HDAC10 | c.*28C>A | 3'UTR (SNP) | VAF 39/313 reads (12%) | catalogued as COSV50569535; called by muse, mutect2, varscan2
- HSH2D | c.215+110G>C | Intron (SNP) | VAF 11/96 reads (11%) | catalogued as rs1268433992; called by muse, mutect2
- MIR1-1HG-AS1 | n.521G>T | RNA (SNP) | VAF 15/143 reads (10%) | catalogued as rs576934853; called by muse, varscan2
- MYADML | n.900C>A | RNA (SNP) | VAF 49/598 reads (8%) | called by muse, mutect2
- NDUFV1 | c.-27G>T | 5'UTR (SNP) | VAF 62/444 reads (14%) | called by muse, mutect2, varscan2
- NETO1 | c.29-376G>T | Intron (SNP) | VAF 14/139 reads (10%) | catalogued as rs1406229232, COSV100199533; called by muse, mutect2
- NLRP2 | c.2537+109C>A | Intron (SNP) | VAF 44/353 reads (12%) | called by muse, mutect2, varscan2
- NUDT16L1 | c.414+208C>T | Intron (SNP) | VAF 5/63 reads (8%) | catalogued as rs1022457266; called by muse, mutect2
- PAFAH1B1 | c.*26C>T | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- PLCB4 | c.1612-2575C>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- PLCXD2 | c.*125del | 3'UTR (DEL) | VAF 14/140 reads (10%) | called by pindel, varscan2
- PLCXD2 | c.*133G>A | 3'UTR (SNP) | VAF 16/124 reads (13%) | called by muse, varscan2
- PLEKHB2 | c.424-65725G>T | Intron (SNP) | VAF 46/484 reads (10%) | called by muse, varscan2
- PRKCA | c.1713+110C>T | Intron (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- PTHLH | c.101+28C>G | Intron (SNP) | VAF 55/229 reads (24%) | called by muse, mutect2, varscan2
- RAB17 | c.435+639G>T | Intron (SNP) | VAF 46/429 reads (11%) | called by muse, mutect2
- SORBS1 | c.2128+1047G>T | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- TARS3 | c.2260+962A>G | Intron (SNP) | VAF 18/197 reads (9%) | catalogued as rs979733499; called by muse, mutect2
- TBL3 | c.*359C>A | 3'UTR (SNP) | VAF 55/336 reads (16%) | called by muse, mutect2, varscan2
- TMEM207 | c.*32A>G | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- TRIM51BP | n.1251T>C | RNA (SNP) | VAF 7/60 reads (12%) | called by mutect2, varscan2
- TSPAN9 | c.*8G>T | 3'UTR (SNP) | VAF 22/189 reads (12%) | called by muse, mutect2, varscan2
- ZEB2 | chr2:144520133 C>A | 5'Flank (SNP) | VAF 58/668 reads (9%) | called by muse, mutect2
- ZNF252P | n.245+4675G>T | Intron (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2
- ZNF451 | c.*71C>T | 3'UTR (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
